Somatic mutation profile of tumor specimen 0DSWA1 from CCDI case PBCIVK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 21.0 years (7,670 days).
Specimen 0DSWA1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46bde351-7046-4061-8b6b-59774723397b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSW9K (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/671df645-78de-42a7-9a97-923d1e031f6e

The open-access MAF lists 34 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 6, Intron 4, Nonsense Mutation 2, Frame Shift Del 2, 5'UTR 2, Frame Shift Ins 2, Splice Site 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAZ2B | c.3532G>A p.E1178K | Missense Mutation (SNP) | VAF 370/845 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs565632225, COSV54276630; called by muse, varscan2
- CGN | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 157/264 reads (59%) | catalogued as rs376940080; called by muse, mutect2, varscan2
- DDX3X | c.789del p.K263Nfs*9 (on ENST00000399959; = p.K264Nfs*9 on NM_001356.5) | Frame Shift Del (DEL) | VAF 222/230 reads (97%) | catalogued as COSV104433637; called by mutect2, varscan2
- HSDL1 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 320/766 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.377); catalogued as rs747743787; called by muse, mutect2, varscan2
- MYH15 | c.4002G>T p.E1334D | Missense Mutation (SNP) | VAF 256/638 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.346); catalogued as COSV56320904; called by mutect2, varscan2
- OIT3 | c.1282G>A p.G428S | Missense Mutation (SNP) | VAF 117/394 reads (30%) | SIFT tolerated (0.28); PolyPhen probably damaging (1); catalogued as rs140962729; called by muse, mutect2, varscan2
- PTGIS | c.1490G>A p.R497H | Missense Mutation (SNP) | VAF 73/358 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs375656558; called by muse, mutect2, varscan2
- RUNDC3A | c.443A>G p.D148G | Missense Mutation (SNP) | VAF 79/245 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56637396; called by muse, mutect2, varscan2
- SCAMP1 | c.71C>T p.T24I | Missense Mutation (SNP) | VAF 307/684 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.348); catalogued as rs1375109843; called by muse, mutect2, varscan2
- TTN | c.48583C>T p.R16195C (on ENST00000591111; = p.R8771C on NM_003319.4) | Missense Mutation (SNP) | VAF 341/721 reads (47%) | PolyPhen probably damaging (0.998); catalogued as rs376153809; called by muse, mutect2, varscan2
- COL17A1 | c.548T>A p.L183H | Missense Mutation (SNP) | VAF 190/593 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CRYL1 | c.453C>G p.Y151* | Nonsense Mutation (SNP) | VAF 140/256 reads (55%) | called by muse, mutect2, varscan2
- CSDE1 | c.582+1G>T p.X194_splice (on ENST00000358528 / NM_001007553.3; = p.X163_splice on NM_007158.6) | Splice Site (SNP) | VAF 189/588 reads (32%) | called by mutect2, varscan2
- GNAS | c.411_412insGTTT p.P138Vfs*3 | Frame Shift Ins (INS) | VAF 257/292 reads (88%) | called by mutect2, varscan2
- INSM1 | c.108dup p.G37Rfs*302 | Frame Shift Ins (INS) | VAF 79/122 reads (65%) | called by mutect2, varscan2
- KLHL22 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 79/365 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MALRD1 | c.4102G>T p.A1368S | Missense Mutation (SNP) | VAF 152/527 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- RXFP1 | c.201del p.W68Gfs*15 | Frame Shift Del (DEL) | VAF 216/516 reads (42%) | called by mutect2, varscan2
- SF3B3 | c.1375G>T p.V459F | Missense Mutation (SNP) | VAF 249/538 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SPATA13 | c.999G>C p.E333D | Missense Mutation (SNP) | VAF 148/399 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- FBXO45 | c.579C>T p.D193= | Silent (SNP) | VAF 216/422 reads (51%) | called by muse, mutect2, varscan2
- IGSF21 | c.147G>A p.K49= | Silent (SNP) | VAF 288/480 reads (60%) | catalogued as COSV52147553; called by muse, mutect2, varscan2
- MYL6 | c.132C>T p.T44= | Silent (SNP) | VAF 253/542 reads (47%) | catalogued as rs758050750; called by muse, mutect2, varscan2
- PCDHA12 | c.2229C>T p.S743= | Silent (SNP) | VAF 206/448 reads (46%) | catalogued as COSV56541107; called by muse, mutect2, varscan2
- PPEF2 | c.1140C>T p.S380= | Silent (SNP) | VAF 286/666 reads (43%) | catalogued as rs947153836; called by muse, mutect2, varscan2
- ZBTB12 | c.514C>T p.L172= | Silent (SNP) | VAF 77/131 reads (59%) | called by muse, mutect2, varscan2
- C5orf38 | c.*20G>T | 3'UTR (SNP) | VAF 223/449 reads (50%) | catalogued as rs1248789705; called by muse, mutect2, varscan2
- DENND4A | chr15:65660324 G>T | 3'Flank (SNP) | VAF 133/467 reads (28%) | called by muse, mutect2, varscan2
- MAOB | c.-42G>C | 5'UTR (SNP) | VAF 78/79 reads (99%) | called by muse, mutect2
- PRELID3A | c.-28G>A | 5'UTR (SNP) | VAF 61/116 reads (53%) | called by muse, mutect2, varscan2
- TARBP2 | c.223+94C>A | Intron (SNP) | VAF 5/99 reads (5%) | called by muse, mutect2
- TMEM214 | c.638-32G>A | Intron (SNP) | VAF 32/115 reads (28%) | called by muse, mutect2, varscan2
- UBN1 | c.433-91G>A | Intron (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2
- UBP1 | c.1271+49C>T | Intron (SNP) | VAF 195/418 reads (47%) | catalogued as rs199877735; called by muse, mutect2, varscan2
